Somatic mutation profile of tumor specimen TCGA-77-8007-01A (aliquot TCGA-77-8007-01A-11D-2184-08) from TCGA case TCGA-77-8007, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.7 years (25,102 days).
Specimen TCGA-77-8007-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9132a0f4-8318-4044-b82f-866f21c419d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8007-11A (Solid Tissue Normal), aliquot TCGA-77-8007-11A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcaeb0c0-e96f-40af-8881-0b1707400102

The open-access MAF lists 94 somatic variants for this specimen: 72 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 20, Nonsense Mutation 7, Splice Site 3, Intron 1, Frame Shift Ins 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.3184C>T p.L1062F (on ENST00000404938 / NM_001163941.2; = p.L617F on NM_178559.6) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99328095; called by muse, mutect2, varscan2
- AC008676.3 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV100400394; called by muse, mutect2
- ADGRL2 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV54695160; called by muse, mutect2, varscan2
- APLNR | c.56G>A p.C19Y | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99951384; called by muse, mutect2
- ARHGAP17 | c.725-1G>T p.X242_splice | Splice Site (SNP) | VAF 31/228 reads (14%) | catalogued as COSV99253260; called by muse, mutect2, varscan2
- CARMIL3 | c.3116T>A p.L1039H | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV100549525; called by muse, mutect2
- CASQ1 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as COSV100927277; called by muse, mutect2, varscan2
- CATSPERB | c.463C>G p.R155G | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56422429, COSV99831126; called by muse, varscan2
- CFH | c.890G>C p.G297A | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661393, COSV62778172; called by muse, mutect2
- CHRNB3 | c.1315G>A p.V439I | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as COSV99251071; called by muse, mutect2
- CNTNAP5 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV101443366, COSV70473991; called by muse, mutect2, varscan2
- CRHBP | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99169474; called by muse, mutect2, varscan2
- DHX38 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs544416921, COSV99194275; called by muse, mutect2, varscan2
- DMXL2 | c.2708A>G p.N903S | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99196225; called by muse, mutect2, varscan2
- DNAH5 | c.11800C>T p.P3934S | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV99448342; called by muse, mutect2, varscan2
- DNAH8 | c.9910G>T p.A3304S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100544452; called by muse, mutect2, varscan2
- DPYSL4 | c.735G>T p.Q245H | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV100633912; called by muse, mutect2
- DUSP9 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as rs782304475, COSV100720098; called by muse, mutect2, varscan2
- ESX1 | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV101006430; called by muse, mutect2
- FARP1 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748243026, COSV60339324, COSV60339449; called by muse, mutect2, varscan2
- FGL2 | c.957T>A p.F319L | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99592465; called by muse, mutect2
- FHOD3 | c.2101G>T p.G701W (on ENST00000359247 / NM_001281739.3; = p.G718W on NM_025135.5) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); catalogued as COSV99940847; called by muse, mutect2
- GGT6 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as COSV54594428; called by muse, mutect2, varscan2
- HDAC4 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1228405569, COSV100613207; called by muse, mutect2
- HSD17B6 | c.785A>T p.N262I | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV100444267; called by muse, mutect2
- IGHV3-74 | c.198G>T p.W66C | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.654); catalogued as rs753127694; called by muse, mutect2
- ISL1 | c.908T>A p.I303K | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV100045290; called by muse, mutect2, varscan2
- JMJD1C | c.3863A>T p.E1288V | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV100550417; called by muse, mutect2, varscan2
- KDR | c.2693T>C p.V898A | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99817334; called by muse, mutect2, varscan2
- LARP4B | c.1501T>A p.Y501N | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.303); catalogued as COSV100295222; called by muse, mutect2
- LCE1B | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.556); catalogued as rs746468932, COSV100780272; called by muse, mutect2, varscan2
- LCE2C | c.108C>A p.C36* | Nonsense Mutation (SNP) | VAF 16/182 reads (9%) | catalogued as COSV100909422; called by muse, mutect2
- LRIG3 | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV100292557; called by muse, mutect2, varscan2
- LY6D | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100009273, COSV56661798; called by muse, mutect2, varscan2
- MAGEE1 | c.2741C>A p.A914D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100819362; called by muse, mutect2, varscan2
- MCAM | c.799C>G p.R267G | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.216); catalogued as COSV50644671, COSV99876078; called by muse, mutect2, varscan2
- MTA3 | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.047); catalogued as COSV101290711; called by muse, mutect2, varscan2
- MYBPC2 | c.2594A>T p.Q865L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV100731762; called by muse, mutect2
- MYZAP | c.526-1G>A p.X176_splice | Splice Site (SNP) | VAF 9/80 reads (11%) | catalogued as COSV99984845; called by muse, mutect2, varscan2
- NDC1 | c.157C>G p.H53D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99323523; called by muse, mutect2, varscan2
- NEFL | c.744C>A p.D248E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0.071); catalogued as rs1388179593, COSV99647943; called by muse, mutect2, varscan2
- NOX4 | c.1446G>T p.K482N | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV54452539, COSV99630221; called by muse, mutect2, varscan2
- NUTM1 | c.2544T>A p.D848E | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100148964; called by muse, mutect2
- OR51L1 | c.370C>G p.R124G | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100386388, COSV58626143; called by muse, mutect2
- PCDH15 | c.475-1G>A p.X159_splice | Splice Site (SNP) | VAF 18/176 reads (10%) | catalogued as COSV100219125, COSV57354800; called by muse, mutect2
- PKHD1L1 | c.2055T>A p.Y685* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV101005956; called by muse, mutect2, varscan2
- PLA2G5 | c.375C>A p.Y125* | Nonsense Mutation (SNP) | VAF 10/119 reads (8%) | catalogued as COSV100908225; called by muse, mutect2
- POLR2E | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1281904434, COSV53123362; called by muse, mutect2
- POSTN | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as COSV101123306; called by muse, mutect2
- PPARGC1B | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs369735274, COSV100494657; called by muse, mutect2, varscan2
- RASA1 | c.2812C>T p.Q938* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as COSV99169665; called by muse, mutect2, varscan2
- RELCH | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.817); catalogued as rs555099518, COSV56884610; called by muse, mutect2, varscan2
- SACS | c.8471C>A p.S2824* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV101207384, COSV66539762; called by muse, mutect2, varscan2
- SCN3A | c.5303C>T p.A1768V | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs765165989, COSV51808405, COSV51816826; called by muse, mutect2, varscan2
- SDS | c.255C>G p.I85M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57452696, COSV99981016; called by muse, mutect2
- SLC25A40 | c.515A>G p.K172R | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.01); catalogued as rs932359006, COSV100353640; called by muse, mutect2
- SRSF8 | c.677C>G p.S226W | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as rs1555107228, COSV101475791, COSV71665506; called by muse, mutect2
- TAS2R40 | c.800C>A p.T267K | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs780417600, COSV101282989; called by muse, mutect2, varscan2
- TENM4 | c.8238G>T p.E2746D | Missense Mutation (SNP) | VAF 61/281 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99573319; called by muse, mutect2, varscan2
- TIAM1 | c.1288G>T p.A430S | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.195); catalogued as rs1190509778, COSV54563729, COSV99734371; called by muse, mutect2, varscan2
- TIAM2 | c.801C>A p.F267L | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.031); catalogued as COSV100018630; called by muse, mutect2
- TICAM1 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV99941072; called by muse, mutect2, varscan2
- TRHDE | c.1978T>C p.W660R | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV99670256; called by muse, mutect2, varscan2
- WASHC5 | c.368A>G p.Q123R | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100572763; called by muse, mutect2, varscan2
- ZNF236 | c.514A>G p.M172V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs781139967, COSV99470105; called by muse, mutect2, varscan2
- ZNF677 | c.1093C>A p.H365N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100447863; called by muse, mutect2, varscan2
- ZNF836 | c.2657G>C p.G886A | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as COSV100440819, COSV59082314; called by muse, mutect2
- ARID2 | c.3547del p.A1183Hfs*5 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | called by mutect2, pindel, varscan2
- C12orf60 | c.730_733dup p.K245Rfs*24 | Frame Shift Ins (INS) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- FHL3 | c.388A>T p.S130C | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.025); called by muse, mutect2
- TMEM132B | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ARL13B | c.1237C>T p.L413= (on ENST00000394222 / NM_001174150.2; = p.L306= on NM_144996.4) | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100114402; called by muse, varscan2
- C16orf90 | c.102C>A p.P34= (on ENST00000399645 / NM_001353385.2; = p.P25= on NM_001080524.2) | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV101290957; called by muse, mutect2, varscan2
- CDH9 | c.1584G>T p.V528= | Silent (SNP) | VAF 45/228 reads (20%) | catalogued as COSV99143266; called by muse, mutect2, varscan2
- CDYL | c.132C>A p.P44= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV100189134; called by muse, mutect2, varscan2
- CLDN25 | c.21A>G p.A7= | Silent (SNP) | VAF 36/148 reads (24%) | catalogued as rs371018780, COSV101493596; called by muse, mutect2, varscan2
- GABRA6 | c.1305G>T p.V435= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV99194298; called by muse, mutect2, varscan2
- JPH2 | c.1032C>T p.N344= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs1413623891, COSV65901626; called by muse, mutect2, varscan2
- LRRK2 | c.3711G>A p.L1237= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV100109844; called by muse, mutect2, varscan2
- LYST | c.7140C>T p.A2380= | Silent (SNP) | VAF 17/288 reads (6%) | catalogued as COSV101089051; called by muse, mutect2
- NCDN | c.750G>A p.P250= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as rs762136596, COSV100357267; called by muse, mutect2
- OR10S1 | c.345T>A p.L115= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1397488677, COSV101602463; called by muse, mutect2, varscan2
- OR1L3 | c.375C>A p.A125= | Silent (SNP) | VAF 26/224 reads (12%) | catalogued as COSV100506234, COSV59169103; called by muse, mutect2
- OR2G6 | c.435C>T p.A145= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs781744459, COSV58574078; called by muse, mutect2, varscan2
- PGPEP1L | c.249C>T p.P83= | Silent (SNP) | VAF 12/129 reads (9%) | catalogued as rs370096055, COSV100967297; called by muse, mutect2, varscan2
- PRKAG3 | c.855C>A p.V285= | Silent (SNP) | VAF 15/133 reads (11%) | catalogued as rs780962142, COSV99291881; called by muse, mutect2, varscan2
- SCARA5 | c.1032C>T p.P344= | Silent (SNP) | VAF 16/170 reads (9%) | catalogued as rs556444276, COSV57280534; called by muse, mutect2
- TIAM2 | c.802C>T p.L268= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV100018635; called by muse, mutect2
- TMEM132B | c.81C>T p.S27= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as COSV100169275; called by muse, mutect2, varscan2
- USH2A | c.1920C>A p.P640= | Silent (SNP) | VAF 17/125 reads (14%) | called by muse, mutect2, varscan2
- ZNF202 | c.12C>T p.A4= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs762246198, COSV100278992, COSV100278994; called by muse, mutect2, varscan2
- RBM44 | c.-98-2931A>G | Intron (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100389766; called by muse, mutect2, varscan2
- TGIF1 | c.-240A>C | 5'UTR (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100394798; called by muse, mutect2, varscan2
